Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A20H, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A20H-06A (Metastatic).

N/A
N/A
N/A
N/A
N/A N/A N/A

DOB/Age/Sex: years Male
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Metastatic melanoma upper R back WLE.
Histopath. Stitch 12 o'clock.

ICD-0-3

Melanoma, NOS 8720/3

Site: SKIN, back 044.5

hw 3/30/11

MACROSCOPIC DESCRIPTION

(Dr

"WIDE EXCISION OF MELANOMA UPPER RIGHT BACK". An orientated ellipse, 130 x 47mm, to a depth of 18mm with a multinodular mass subcutaneously 50 x 30mm. One full slice taken at 8 x 5mm of largest nodule for tissue banking. The stitch is placed in the 12 o'clock position. The 12 o'clock inked blue the 6 o'clock inked black. A diagram is on the request form.

The centre of the skin shows a linear scar 35 x 4mm. The nodule is under the scar and is 5mm from the 12 o'clock margin 13mm from the 6 o'clock margin and well away from the 3 o'clock and 9 o'clock poles.

A - B. one bisected transverse section from the nodule
C - D. Second bisected section

MICROSCOPIC REPORT

"WIDE EXCISION OF MELANOMA UPPER RIGHT BACK"

The sections show skin with marked solar elastosis to the level of subcutis. Within the dermis and subcutis is a relatively well-circumscribed, unencapsulated lobulated tumour composed of epithelioid to spindled cells. The cells are large with pleomorphic, oval nuclei, coarse chromatin and a large nucleolus. Plentiful mitotic figures are seen and there are areas of necrosis. Intracytoplasmic pigment is not identified. The overlying epidermis is unremarkable.

The tumour cells are strongly patchily positive for S100, and negative for HMB45 and Melan A. The features are consistent with metastatic melanoma.

The tumour nodule is 2.1mm from the deep margin and 7mm from the closest radial black inked 6 o'clock margin.

SUMMARY

Skin, right upper back - Melanoma, please see report.

REPORTED BY: Dr. C

Printed:

Source: NCI Genomic Data Commons file a17e1f4a-bcab-4e07-89e5-5926b0e8b5ab (TCGA-EE-A20H.85809002-468D-4683-9D69-01B3F9D2C920.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).